Somatic mutation profile of tumor specimen 0DAOBO from CCDI case PBBKDK, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Vital status: Alive; Primary diagnosis: Medulloblastoma, NOS; Tissue or organ of origin: Cerebellum, NOS; Age at diagnosis: 16.3 years (5,961 days).
Specimen 0DAOBO: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 1b0138a1-cd8f-4b07-8584-1168c5fde507.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DAOBP (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/3947cdcb-0186-4793-aab9-e48a5faf259a

The open-access MAF lists 37 somatic variants for this specimen: 27 protein-altering or splice-affecting, 7 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 21, Silent 7, Nonsense Mutation 4, Intron 2, Frame Shift Ins 1, 3'UTR 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CTNNB1 | c.98C>A p.S33Y | Missense Mutation (SNP) | VAF 183/442 reads (41%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs121913400, COSV62687839, COSV62688300, COSV62688644; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- AL662899.2 | c.257G>A p.R86H | Missense Mutation (SNP) | VAF 143/226 reads (63%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); catalogued as rs372125807; called by muse, mutect2, varscan2
- C16orf89 | c.226C>T p.R76W | Missense Mutation (SNP) | VAF 84/297 reads (28%) | SIFT tolerated (0.09); PolyPhen benign (0.01); catalogued as rs761975801, COSV60125069; called by muse, mutect2, varscan2
- CUL1 | c.1453G>A p.E485K | Missense Mutation (SNP) | VAF 26/460 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as COSV57386998; called by muse, mutect2
- DDX3X | c.1421G>A p.R474H (on ENST00000399959; = p.R475H on NM_001356.5) | Missense Mutation (SNP) | VAF 108/368 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.858); catalogued as COSV67863186; called by muse, mutect2, varscan2
- DPP10 | c.548C>T p.A183V | Missense Mutation (SNP) | VAF 96/371 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1197469756, COSV59696895; called by muse, mutect2, varscan2
- EIF2S1 | c.164G>A p.R55H | Missense Mutation (SNP) | VAF 22/432 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53599267; called by muse, mutect2
- FOXP2 | c.1657C>T p.R553C | Missense Mutation (SNP) | VAF 180/581 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs566961630; called by muse, mutect2, varscan2
- FSD2 | c.466C>T p.R156C | Missense Mutation (SNP) | VAF 85/235 reads (36%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.926); catalogued as rs770864728; called by muse, mutect2, varscan2
- HELZ2 | c.2156G>A p.R719H (on ENST00000467148 / NM_001037335.2; = p.R150H on NM_033405.3) | Missense Mutation (SNP) | VAF 50/146 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100915416; called by muse, mutect2, varscan2
- INCENP | c.1137dup p.E380Rfs*4 | Frame Shift Ins (INS) | VAF 90/258 reads (35%) | catalogued as rs34042792; called by mutect2, varscan2
- KMT2D | c.16450G>T p.E5484* | Nonsense Mutation (SNP) | VAF 222/613 reads (36%) | catalogued as COSV56433117; called by muse, mutect2, varscan2
- MTMR11 | c.1444C>T p.R482C (on ENST00000439741 / NM_001145862.2; = p.R410C on NM_181873.3) | Missense Mutation (SNP) | VAF 153/418 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs782646705; called by muse, varscan2
- PPP1R3A | c.713C>T p.P238L | Missense Mutation (SNP) | VAF 193/664 reads (29%) | SIFT tolerated (0.31); PolyPhen benign (0.007); catalogued as rs767708891, COSV99492012; called by muse, mutect2, varscan2
- RYR1 | c.2903C>T p.P968L | Missense Mutation (SNP) | VAF 101/298 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs1272027787, COSV62098237, COSV62110744; called by muse, mutect2, varscan2
- SPNS1 | c.860C>T p.T287M | Missense Mutation (SNP) | VAF 173/549 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.926); catalogued as COSV57957034; called by muse, mutect2, varscan2
- TCF4 | c.1720C>T p.R574C | Missense Mutation (SNP) | VAF 26/551 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as CM125348, COSV61906615; called by muse, mutect2
- TRIM2 | c.881G>A p.R294Q (on ENST00000437508; = p.R321Q on NM_015271.5 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 153/602 reads (25%) | SIFT tolerated (0.18); PolyPhen benign (0.005); catalogued as rs368629463, COSV100107985; called by muse, mutect2, varscan2
- AKAP13 | c.205A>C p.K69Q | Missense Mutation (SNP) | VAF 123/320 reads (38%) | SIFT deleterious (0.04); PolyPhen benign (0.236); called by muse, mutect2, varscan2
- ARHGAP44 | c.198+1G>A p.X66_splice | Splice Site (SNP) | VAF 95/225 reads (42%) | called by muse, mutect2, varscan2
- ASCC3 | c.3205G>T p.E1069* | Nonsense Mutation (SNP) | VAF 20/354 reads (6%) | called by muse, mutect2
- CADPS2 | c.2040C>A p.Y680* | Nonsense Mutation (SNP) | VAF 27/620 reads (4%) | called by muse, mutect2
- DCAF12L2 | c.660G>T p.W220C | Missense Mutation (SNP) | VAF 21/382 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- FREM3 | c.5553T>A p.Y1851* | Nonsense Mutation (SNP) | VAF 155/481 reads (32%) | called by mutect2, varscan2
- HCK | c.1117G>A p.E373K | Missense Mutation (SNP) | VAF 20/520 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2
- PFKP | c.98G>A p.G33D | Missense Mutation (SNP) | VAF 19/281 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- ZDHHC22 | c.691C>T p.R231C | Missense Mutation (SNP) | VAF 61/321 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.642); called by muse, mutect2, varscan2
- ATP1A3 | c.33C>T p.I11= | Silent (SNP) | VAF 53/201 reads (26%) | catalogued as rs782779217, COSV100132263; called by muse, mutect2, varscan2
- DMP1 | c.516C>T p.D172= | Silent (SNP) | VAF 20/397 reads (5%) | called by muse, mutect2
- KLRC2 | c.490C>T p.L164= | Silent (SNP) | VAF 40/722 reads (6%) | catalogued as rs113401718; called by muse, mutect2
- KRT5 | c.1536C>A p.L512= | Silent (SNP) | VAF 224/678 reads (33%) | called by muse, mutect2
- OR7G2 | c.852G>A p.V284= | Silent (SNP) | VAF 33/151 reads (22%) | catalogued as rs547475191; called by mutect2, varscan2
- PRKCQ | c.6G>T p.S2= | Silent (SNP) | VAF 89/233 reads (38%) | catalogued as COSV99577696; called by muse, mutect2, varscan2
- SARDH | c.1161G>A p.T387= | Silent (SNP) | VAF 80/262 reads (31%) | catalogued as rs370661854; called by muse, mutect2, varscan2
- C17orf107 | c.*1301C>T | 3'UTR (SNP) | VAF 11/39 reads (28%) | catalogued as COSV53419967; called by muse, mutect2, varscan2
- KDM5B | c.1197+23G>A | Intron (SNP) | VAF 10/251 reads (4%) | called by muse, mutect2
- PLD2 | c.241-36C>T | Intron (SNP) | VAF 14/58 reads (24%) | catalogued as rs755949788; called by muse, mutect2, varscan2
